Somatic mutation profile of tumor specimen 0DU81G from CCDI case PBCKTP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 11.3 years (4,135 days).
Specimen 0DU81G: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 050a40a4-9da1-4353-8b74-1ad06078b21a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU80E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0bc5877-4e61-4f11-a6f9-81db21ef08b4

The open-access MAF lists 83 somatic variants for this specimen: 55 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Intron 6, Nonsense Mutation 4, 5'UTR 3, 5'Flank 2, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HADHA | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 42/576 reads (7%) | catalogued as rs137852771, CM960808, COSV101024099; ClinVar: pathogenic; called by muse, mutect2
- ADGRG6 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 79/571 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as rs756610632, COSV51589664; called by muse, mutect2, varscan2
- ADGRL3 | c.3961G>C p.A1321P (on ENST00000506720 / NM_001322402.2; = p.A1210P on NM_015236.6) | Missense Mutation (SNP) | VAF 95/723 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV72230673, COSV72231555; called by muse, mutect2, varscan2
- ATG2A | c.5795G>A p.R1932H | Missense Mutation (SNP) | VAF 93/640 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63475534; called by muse, mutect2, varscan2
- CUZD1 | c.1673C>G p.A558G | Missense Mutation (SNP) | VAF 83/638 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV59026982; called by muse, mutect2, varscan2
- FCGR2B | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 90/430 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs1240895640; called by muse, mutect2, varscan2
- FRRS1 | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 120/746 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201530272, COSV54926081; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.388G>C p.D130H (on ENST00000354667 / NM_031243.3; = p.D118H on NM_002137.4) | Missense Mutation (SNP) | VAF 116/974 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs951126354; called by muse, mutect2, varscan2
- INPP5D | c.1318G>C p.D440H (on ENST00000445964 / NM_001017915.3; = p.D439H on NM_005541.5) | Missense Mutation (SNP) | VAF 89/608 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as COSV64038547; called by muse, mutect2, varscan2
- LIMD2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 93/765 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as rs778234120, COSV51991207; called by muse, mutect2, varscan2
- MAGEL2 | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 73/439 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs548982518; called by muse, mutect2, varscan2
- MAP3K1 | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 83/705 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs375893442; called by muse, mutect2, varscan2
- MCCC1 | c.957G>A p.G319= | Splice Region (SNP) | VAF 59/223 reads (26%) | catalogued as COSV99659435; called by muse, mutect2, varscan2
- PAQR9 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 89/488 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757779427, COSV61418252; called by muse, mutect2, varscan2
- PARN | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 86/598 reads (14%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs754373655; called by muse, mutect2, varscan2
- PENK | c.779G>C p.R260T | Missense Mutation (SNP) | VAF 92/914 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473828696, COSV100152411, COSV59243276; called by muse, mutect2
- PRSS53 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 130/841 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375690216, COSV54922395; called by muse, mutect2, varscan2
- RBM19 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 86/677 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs371958264; called by muse, mutect2, varscan2
- RGS2 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 114/654 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV99343304; called by muse, varscan2
- SLC22A11 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 81/683 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs757063285; called by muse, mutect2, varscan2
- TENM2 | c.2750T>C p.I917T (on ENST00000518659 / NM_001122679.2; = p.I685T on NM_001080428.3) | Missense Mutation (SNP) | VAF 85/658 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as COSV101319055; called by muse, mutect2, varscan2
- USHBP1 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 43/397 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1271211327; called by muse, mutect2, varscan2
- WASHC5 | c.2731A>G p.T911A | Missense Mutation (SNP) | VAF 105/1198 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV59196061; called by muse, mutect2
- ZFYVE16 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751754470; called by muse, mutect2, varscan2
- ZNF517 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 44/564 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs772832393, COSV63464806; called by muse, mutect2
- AHNAK | c.7003C>G p.P2335A | Missense Mutation (SNP) | VAF 32/942 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- AQR | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 65/429 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP44 | c.2188C>A p.P730T | Missense Mutation (SNP) | VAF 144/863 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- CCL20 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 122/687 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CNGB3 | c.1127A>T p.N376I | Missense Mutation (SNP) | VAF 148/1934 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2
- CNOT1 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 106/608 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL11A2 | c.76T>A p.W26R | Missense Mutation (SNP) | VAF 88/540 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- DIAPH2 | c.2710G>T p.A904S | Missense Mutation (SNP) | VAF 70/448 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERI2 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 100/682 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.084); called by muse, varscan2
- EXOC4 | c.1598A>C p.K533T | Missense Mutation (SNP) | VAF 91/819 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FLNA | c.3509T>C p.L1170P | Missense Mutation (SNP) | VAF 135/878 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INPP4A | c.376T>C p.S126P | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- IRX4 | c.1335C>A p.D445E | Missense Mutation (SNP) | VAF 92/678 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KIR2DS4 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 170/1148 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- LHCGR | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 29/1182 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- MAGEA3 | c.524T>A p.L175* | Nonsense Mutation (SNP) | VAF 44/1370 reads (3%) | called by muse, mutect2
- NOVA2 | c.89A>G p.E30G | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.173); called by muse, mutect2
- OR1L1 | c.927T>A p.Y309* (on ENST00000373686; = p.Y259* on NM_001005236.3) | Nonsense Mutation (SNP) | VAF 83/578 reads (14%) | called by muse, mutect2, varscan2
- PGAP2 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 65/590 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHF14 | c.1874-1G>C p.X625_splice | Splice Site (SNP) | VAF 23/490 reads (5%) | called by muse, mutect2
- PLIN1 | c.1295A>G p.E432G | Missense Mutation (SNP) | VAF 53/398 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- POLR2B | c.3272G>A p.R1091Q | Missense Mutation (SNP) | VAF 81/495 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGER4 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 68/542 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SCAF8 | c.1586T>G p.L529R | Missense Mutation (SNP) | VAF 60/489 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- SEZ6L | c.388A>T p.K130* | Nonsense Mutation (SNP) | VAF 106/621 reads (17%) | called by muse, mutect2, varscan2
- SMAP2 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 60/521 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- SNX20 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 100/628 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNKS | c.1640A>C p.K547T | Missense Mutation (SNP) | VAF 94/1197 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- TTN | c.15330C>A p.F5110L (on ENST00000591111; = p.F4183L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/888 reads (11%) | PolyPhen benign (0.225); called by muse, mutect2, varscan2
- UTRN | c.8339G>C p.R2780P | Missense Mutation (SNP) | VAF 60/485 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- A2M | c.264C>T p.A88= | Silent (SNP) | VAF 56/615 reads (9%) | catalogued as rs769067573; called by muse, mutect2
- ACTL9 | c.1146C>A p.I382= | Silent (SNP) | VAF 10/268 reads (4%) | catalogued as rs1223526819, COSV61006667; called by muse, mutect2
- C10orf90 | c.2046C>T p.A682= | Silent (SNP) | VAF 136/799 reads (17%) | catalogued as rs757743695; called by muse, mutect2, varscan2
- CACNA1E | c.4356C>T p.S1452= | Silent (SNP) | VAF 112/773 reads (14%) | catalogued as rs571237279, COSV62393227; called by muse, mutect2, varscan2
- CHRDL1 | c.534G>T p.L178= (on ENST00000372045; = p.L184= on NM_145234.4) | Silent (SNP) | VAF 13/343 reads (4%) | called by muse, mutect2
- EDA2R | c.324G>A p.T108= | Silent (SNP) | VAF 85/545 reads (16%) | catalogued as rs774938733, COSV53630732; called by muse, mutect2, varscan2
- GFPT1 | c.819G>C p.V273= (on ENST00000357308 / NM_001244710.2; = p.V255= on NM_002056.4) | Silent (SNP) | VAF 80/594 reads (13%) | catalogued as COSV61948871; called by muse, mutect2, varscan2
- GLB1L3 | c.1053C>T p.N351= | Silent (SNP) | VAF 33/322 reads (10%) | catalogued as rs373860571; called by muse, mutect2, varscan2
- MUC16 | c.12396A>C p.S4132= | Silent (SNP) | VAF 76/507 reads (15%) | catalogued as COSV67495821; called by muse, mutect2, varscan2
- NCOA5 | c.1362G>A p.S454= | Silent (SNP) | VAF 233/1040 reads (22%) | catalogued as rs746853219, COSV51644702; called by muse, mutect2, varscan2
- NUP155 | c.225A>G p.V75= (on ENST00000231498 / NM_153485.3; = p.V16= on NM_004298.4) | Silent (SNP) | VAF 48/366 reads (13%) | called by muse, mutect2, varscan2
- OR51V1 | c.93C>A p.S31= | Silent (SNP) | VAF 92/680 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.33C>G p.G11= | Silent (SNP) | VAF 128/1121 reads (11%) | called by muse, mutect2, varscan2
- PLCB3 | c.2352C>T p.P784= | Silent (SNP) | VAF 95/836 reads (11%) | catalogued as rs1439126937; called by muse, mutect2, varscan2
- ROR1 | c.2490G>A p.A830= | Silent (SNP) | VAF 131/800 reads (16%) | catalogued as rs146764088; called by muse, mutect2, varscan2
- ZNF789 | c.882T>C p.F294= | Silent (SNP) | VAF 111/843 reads (13%) | called by muse, mutect2, varscan2
- AL513164.1 | n.205+7947C>A | Intron (SNP) | VAF 61/386 reads (16%) | catalogued as rs749541731; called by muse, mutect2, varscan2
- C6orf47 | c.-4A>T | 5'UTR (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- CTDNEP1 | c.-75C>T | 5'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- DNAH2 | c.1170+747C>A | Intron (SNP) | VAF 98/596 reads (16%) | called by muse, mutect2, varscan2
- IGSF22 | c.*323T>A | 3'UTR (SNP) | VAF 11/379 reads (3%) | catalogued as rs1257958181; called by muse, mutect2
- MAN2A2 | c.1010-19C>T | Intron (SNP) | VAF 29/174 reads (17%) | catalogued as rs777402674, COSV64637758; called by muse, mutect2, varscan2
- NOS2P4 | chr17:16812435 G>A | 5'Flank (SNP) | VAF 53/593 reads (9%) | called by muse, mutect2
- REG3G | c.76+74G>T | Intron (SNP) | VAF 54/335 reads (16%) | catalogued as rs1315631515; called by muse, mutect2, varscan2
- RPL14 | c.-25T>G | 5'UTR (SNP) | VAF 98/629 reads (16%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.254+59C>A | Intron (SNP) | VAF 33/156 reads (21%) | called by muse, mutect2, varscan2
- TLE5 | chr19:3062988 C>T | 5'Flank (SNP) | VAF 10/74 reads (14%) | catalogued as rs56193569; called by muse, mutect2
- ZNF605 | c.136+267G>A | Intron (SNP) | VAF 16/518 reads (3%) | called by muse, mutect2
